MMRF case MMRF_2550 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/7fee4128-0366-41b1-b706-a83ecaa53cc0

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 62.9 years (22,969 days); ISS stage: III; Days to last known disease status: 249 days; Days to last follow up: 249 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 249.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -17 (ECOG 1): M Protein 5.79 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.66 mg/dL; Immunoglobulin G 67.6 g/L; Immunoglobulin A 0.75 g/L; Immunoglobulin M 0.38 g/L; Beta 2 Microglobulin 6.43 µg/mL; Lactate Dehydrogenase 3.5 µkat/L; Hemoglobin 4.9 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.3 mmol/L; Albumin 33 g/L; Total Protein 11.3 g/dL; Glucose 5.06 mmol/L; C-Reactive Protein 0.34 mg/dL.
- Day 102 (ECOG 1): M Protein 1.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 12.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.26 mg/dL; Immunoglobulin G 21.2 g/L; Immunoglobulin A 1.94 g/L; Immunoglobulin M 0.42 g/L; Lactate Dehydrogenase 3.72 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 8.2 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.43 mmol/L; Albumin 38 g/L; Total Protein 7.5 g/dL; Glucose 5.06 mmol/L.
- Day 200 (ECOG 0): M Protein 1.37 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 13.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.27 mg/dL; Immunoglobulin G 20.1 g/L; Immunoglobulin A 2.02 g/L; Immunoglobulin M 0.5 g/L; Beta 2 Microglobulin 3.71 µg/mL; Lactate Dehydrogenase 4.42 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 8.7 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 245 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 7.5 g/dL; Glucose 6.11 mmol/L.

Other clinical attributes
- Day -17: Weight: 86 kg; Height: 160 cm.

Biospecimens (2 samples)
- Sample MMRF_2550_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -17 days.
- Sample MMRF_2550_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -17 days.
